Gene-level copy-number profile of tumor specimen TCGA-A5-A3LP-01A from TCGA case TCGA-A5-A3LP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 74.3 years (27,131 days).
Specimen TCGA-A5-A3LP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.42bb894c-2eb0-44ff-9cce-e9733fc7a6ca.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A5-A3LP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/878b95ca-d7c1-4e9a-8732-9d270d53a95e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 633; copy number 2: 11,185; copy number 3: 19,049; copy number 4: 14,216; copy number 5: 6,706; copy number 6: 6,157; copy number 7: 769; copy number 8: 209; copy number 9: 824; copy number 10: 26; copy number 12: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A5-A3LP-01A-11D-A227-01): tumor purity 0.61, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,394 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,383,838–41,383,590, 101 genes, copy number 7 (broad region; genes not listed).
- chr1:47,333,797–50,023,954, 33 genes, copy number 9 (within-gene range 4–9): CMPK1, LINC01389, FOXE3, FOXD2-AS1, FOXD2, AL356458.1, RPL21P24, ATP6V0E1P4, LINC01738, TRABD2B, AL691459.1, AC096541.1, LINC02794, AL356289.1, CYP46A4P, SKINT1L, AL356289.2, AL109659.1, SLC5A9, AL109659.2, AL109659.3, SPATA6, PPP1R8P1, RNU6-723P, AL356968.2, RNU4-61P, AL356968.1, AGBL4, AL391844.1, BEND5, AL645507.1, AC099788.1, AGBL4-AS1.
- chr1:143,343,180–156,177,752, 592 genes, copy number 9–12 (broad region; genes not listed).
- chr2:112,829,751–113,756,693, 41 genes, copy number 9: IL1B, AC079753.1, XIAPP3, IL37, CDK8P2, IL36G, HMGN2P23, POLR2DP1, IL36A, IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P, SLC35F5, MIR4782.
- chr3:101,878,333–101,997,926, 4 genes, copy number 7: AC020651.2, LINC02085, Y_RNA, AC106712.1.
- chr5:36,485,343–37,085,852, 11 genes, copy number 10: RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6.
- chr6:125,219,962–126,258,355, 13 genes, copy number 8 (within-gene range 4–8): HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5.
- chr8:129,685,401–137,092,183, 88 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr9:3,526,723–3,691,814, 3 genes, copy number 7 (within-gene range 3–7): RFX3-AS1, AL354977.2, AL354977.1.
- chr10:44,712–2,502,200, 38 genes, copy number 7 (within-gene range 5–7): AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1, AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645.
- chr11:55,279,447–55,787,905, 31 genes, copy number 8–9: AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P, OR4A12P, OR4A16, OR4A15, OR4A9P, OR4X7P, OR4A10P, OR4A17P, OR4A13P, OR4A50P, OR4A21P, OR4C1P, OR4C14P, OR4C15, OR4C16, OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1, OR5D2P, OR5D3P, OR5D17P, OR5D13, OR5D15P.
- chr12:6,742,985–7,240,986, 45 genes, copy number 7: AC125494.2, MLF2, PTMS, LAG3, RN7SL380P, CD4, GPR162, P3H3, GNB3, CDCA3, USP5, TPI1, SPSB2, RPL13P5, LRRC23, DSTNP2, U47924.3, ENO2, ATN1, C12orf57, U47924.2, RNU7-1, PTPN6, MIR200CHG, MIR200C, MIR141, U47924.1, PHB2, SCARNA12, EMG1, LPCAT3, C1S, AC006512.1, AC006512.2, C1R, C1RL, C1RL-AS1, RBP5, RNU6-485P, AC018653.3, CLSTN3, AC018653.4, AC018653.1, PEX5, AC018653.2.
- chr14:20,891,399–21,116,703, 24 genes, copy number 9: RNASE3, AL355922.4, AL355922.3, AL355922.1, RNASE2, RN7SL189P, AL355922.2, METTL17, AL161668.3, SLC39A2, NDRG2, MIR6717, TPPP2, AL161668.4, AL161668.2, RNASE13, RNASE7, RNASE8, ARHGEF40, ZNF219, TMEM253, AL161668.1, CKAP2P1, RNU6-252P.
- chr14:21,978,459–22,867,917, 124 genes, copy number 9 (broad region; genes not listed).
- chr14:99,604,556–100,530,303, 30 genes, copy number 8 (within-gene range 5–8): AL160313.1, HHIPL1, CYP46A1, AL160313.2, EML1, RNU1-47P, VDAC3P1, EVL, AL133368.1, AL133368.2, AL157912.1, MIR151B, MIR342, DEGS2, AL133523.1, YY1, AL157871.5, MIR6764, AL157871.6, SLC25A29, AL157871.1, MIR345, RN7SL523P, SLC25A47, AL157871.4, WARS1, AL157871.2, AL157871.3, WDR25, AL135838.1.
- chr19:44,326,555–45,092,635, 44 genes, copy number 9: ZNF112, AC245748.1, ZNF285, AC245748.2, ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3, CEACAM22P, AC243964.1, IGSF23, AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, AC092306.1, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1, APOC1P1, APOC4, APOC4-APOC2, APOC2, AC011481.1, CLPTM1, RELB, CLASRP, RNU6-611P, ZNF296, GEMIN7-AS1, GEMIN7.
- chr19:45,091,396–45,148,077, 1 gene, copy number 9 (within-gene range 6–9): PPP1R37.
- chr20:53,552,770–56,786,087, 46 genes, copy number 7–10: AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, AL109806.2, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P.
- chr21:10,328,411–18,760,320, 125 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 633. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
